Somatic mutation profile of tumor specimen TCGA-28-6450-01A (aliquot TCGA-28-6450-01A-11D-1696-08) from TCGA case TCGA-28-6450, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.7 years (22,177 days).
Specimen TCGA-28-6450-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 951b1e71-b89b-4b59-8cb2-89721e09921f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-6450-10A (Blood Derived Normal), aliquot TCGA-28-6450-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa5c54fa-00e6-45e8-b53b-65e61f4720bd

The open-access MAF lists 61 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Frame Shift Del 4, Nonsense Mutation 2, Intron 1, Splice Region 1, 5'Flank 1, 3'Flank 1, RNA 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AIM2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs149324922; called by muse, mutect2, varscan2
- AZIN2 | c.1168T>A p.Y390N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV53859216; called by muse, mutect2, varscan2
- CCPG1 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51242928; called by muse, mutect2, varscan2
- COL11A2 | c.2509C>T p.R837W (on ENST00000341947 / NM_080680.3; = p.R730W on NM_080679.2) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761256686, COSV59499617, COSV59499639; called by muse, mutect2, varscan2
- CUBN | c.10409G>A p.C3470Y | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64721685, COSV64729889; called by muse, mutect2, varscan2
- CUX2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as rs780487031, COSV55640168, COSV99920259; called by muse, mutect2, varscan2
- EFNA3 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV63625816; called by muse, mutect2, varscan2
- FGG | c.1011G>T p.Q337H | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.054); catalogued as COSV60196049; called by muse, mutect2, varscan2
- FLG | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64236425, COSV64244942; called by muse, mutect2
- GPR107 | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV100714771, COSV61281093; called by muse, mutect2, varscan2
- GPR34 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59371573; called by muse, mutect2, varscan2
- HCN1 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs141383188; called by mutect2, varscan2
- IDO1 | c.654C>T p.H218= | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as rs773520481, COSV53715320; called by muse, mutect2
- IFT140 | c.3122A>T p.N1041I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV54153866; called by muse, mutect2, varscan2
- KRT31 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs749601131, COSV52436771; called by muse, mutect2, varscan2
- KYNU | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51579486, COSV51587701; called by muse, mutect2, varscan2
- L1CAM | c.3590G>A p.G1197E | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.979); catalogued as COSV100649428, COSV62829076; called by muse, mutect2, varscan2
- LAMA1 | c.5596G>A p.D1866N | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs768494041, COSV67540365; called by muse, mutect2, varscan2
- LCP1 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as COSV59942214, COSV59942677; called by muse, mutect2, varscan2
- LRP2 | c.8809G>A p.E2937K | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746934443, COSV55563728; called by muse, mutect2, varscan2
- ME2 | c.1094T>G p.F365C | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58424266; called by muse, mutect2, varscan2
- NF1 | c.1019_1020del p.S340Cfs*12 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | catalogued as rs1555610903; called by pindel, varscan2
- NF1 | c.7970+4_7970+7del p.X2657_splice (on ENST00000358273 / NM_001042492.3; = p.X2636_splice on NM_000267.3) | Splice Site (DEL) | VAF 15/62 reads (24%) | catalogued as rs1064794279; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NKAPL | c.664A>G p.R222G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.368); catalogued as COSV59198605; called by muse, mutect2, varscan2
- NOX3 | c.1180A>T p.T394S | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99343109; called by muse, mutect2, varscan2
- OR6C75 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV58552303; called by muse, mutect2, varscan2
- PCDHA7 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as COSV65342359; called by muse, mutect2, varscan2
- PEG3 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55624758, COSV55640636; called by muse, mutect2, varscan2
- PEG3 | c.1266G>C p.M422I | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV55640645; called by muse, mutect2, varscan2
- PLEKHG4B | c.1521G>T p.Q507H (on ENST00000283426; = p.Q863H on NM_052909.5) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV52051244; called by muse, mutect2, varscan2
- PRKG2 | c.454del p.D152Tfs*18 | Frame Shift Del (DEL) | VAF 135/447 reads (30%) | catalogued as COSV52328957; called by mutect2, pindel, varscan2
- RGS6 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs767452040, COSV59587816; called by muse, mutect2, varscan2
- RUVBL1 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59476518; called by muse, mutect2, varscan2
- SHCBP1L | c.1056G>C p.M352I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV62356058; called by muse, mutect2, varscan2
- TAF1L | c.3391A>G p.K1131E | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV54265275; called by muse, mutect2, varscan2
- TBC1D3B | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 84/458 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs765298758; called by muse, mutect2, varscan2
- TLR5 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); catalogued as rs201906412, COSV60559266; called by muse, mutect2, varscan2
- UGT2A3 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52361188; called by muse, mutect2, varscan2
- ZNF275 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV64704982; called by muse, mutect2
- ZNF350 | c.24A>G p.I8M | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV54709760; called by muse, mutect2, varscan2
- ZNF629 | c.130A>C p.I44L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV52699627; called by muse, mutect2, varscan2
- ZNF768 | c.1565T>C p.F522S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100776243; called by muse, mutect2, varscan2
- ZNF768 | c.1564T>G p.F522V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100776244; called by muse, mutect2, varscan2
- DHX57 | c.1330del p.S444Lfs*5 | Frame Shift Del (DEL) | VAF 54/180 reads (30%) | called by mutect2, pindel, varscan2
- STAU1 | c.1152del p.F386Lfs*23 (on ENST00000371856 / NM_001319135.1; = p.F305Lfs*23 on NM_004602.3) | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- AQP10 | c.84T>C p.F28= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV61475762; called by muse, mutect2, varscan2
- DNAJC11 | c.858A>G p.R286= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV53788754; called by muse, varscan2
- FBXO8 | c.669C>G p.A223= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV67031826; called by muse, mutect2, varscan2
- GPD1L | c.345G>A p.A115= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs149167213; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEC3 | c.324G>A p.P108= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs182076629, COSV71610090; called by muse, mutect2, varscan2
- MFSD10 | c.354G>A p.P118= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1418309550, COSV53271603; called by muse, mutect2, varscan2
- NOX3 | c.1179G>T p.L393= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as COSV50149917; called by muse, mutect2, varscan2
- PCDHGB3 | c.1794G>A p.S598= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as rs771970227, COSV53908773, COSV53989508; called by muse, mutect2, varscan2
- POLG | c.570C>T p.P190= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV51523314; called by muse, mutect2
- SLC12A5 | c.906C>T p.F302= (on ENST00000454036 / NM_001134771.2; = p.F279= on NM_020708.5) | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs771523031, COSV54797760; called by muse, mutect2, varscan2
- ABCC9 | chr12:21801159 G>A | 3'Flank (SNP) | VAF 25/72 reads (35%) | catalogued as rs554811993, COSV53973652; ClinVar: not provided; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500511 del GTG | 5'Flank (DEL) | VAF 10/32 reads (31%) | called by pindel, varscan2
- CHST8 | c.-2G>A | 5'UTR (SNP) | VAF 33/88 reads (38%) | catalogued as rs572454321, COSV52861829; called by muse, mutect2, varscan2
- OBSCN | c.11659+4340C>G | Intron (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99477204, COSV99481621; called by muse, mutect2, varscan2
- PKD1L2 | n.1065C>T | RNA (SNP) | VAF 49/114 reads (43%) | called by muse, mutect2, varscan2
